ALCHEMIST case ALCH-B3IY — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/cc9ffeff-1080-45d9-abf7-0e39f8e5705e

Demographics
Sex at birth: female.

Diagnoses (1)
1. Adenocarcinoma, NOS: Age at diagnosis: 75.3 years (27,495 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-B3IY-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-B3IY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-B3IY-TTP1-A-1-0-S1: Section location: Bottom; Percent tumor cells: 59; Percent tumor nuclei: 74; Percent normal cells: 4; Percent necrosis: 0; Percent stromal cells: 37; Percent lymphocyte infiltration: 21; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
  Slide ALCH-B3IY-TTP1-A-1-0-S2: Section location: Top; Percent tumor cells: 30; Percent tumor nuclei: 30; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 60; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 0.
